MP2PRT case MP2PRT-PAUWCD — Molecular Profiling to Predict Response to Treatment - Wilms Tumor (MP2PRT-WT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/a4278e48-c828-423b-9271-ae5a647f0726

Demographics
Sex at birth: male; Ethnicity: not hispanic or latino; Year of birth: 2011; Vital status: Alive.

Diagnoses (1)
1. Nephroblastoma, NOS: ICD-O-3 morphology code: 8960/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 0.5 years (184 days); Wilms tumor histologic subtype: Favorable.
   Treatment — whether it was given is not recorded by GDC; Regimen or line of therapy: Unknown (Not Submitted).

Biospecimens (3 samples)
- Sample MP2PRT-PAUWCD-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Cryopreserved.
- Sample MP2PRT-PAUWCD-TTM2-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Cryopreserved.
- Sample MP2PRT-PAUWCD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Cryopreserved.
